Surgical pathology report (de-identified scan), TCGA case TCGA-44-A4SU, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-A4SU-01A (Primary Tumor).

Final Surgical Pathology Report

Procedure:

Diagnosis

A. Lung, right lower lobe, excisional biopsy: Moderately differentiated adenocarcinoma

B. Lung, right lower lobe, reexcision of staple line: Negative for malignancy

Microscopic Description:

A.

Histologic type: Adenocarcinoma with some lepidic growth. There are some tumor cell clusters in adjacent alveoli.

Histologic grade: 2

Tumor size: 1.8 cm

Pulmonary margin of resection: Carcinoma is present in sections taken near the staple line, but specimen B. (reexcision of staple line) is negative for malignancy.

Pleura: Negative for malignancy

Vascular invasion: Focal features suspicious for vascular invasion

pTNM stage: T1a

Specimen

A. Right lower lobe

B. Reexcision of staple line

Clinical Information

Lung nodule

1CD-0-3

adenocarcinoma, NOS 8/40/3

Site: Lung, (R) Lower lobe C34.3

fw
10/27/12

Gross Description

The specimen is received unfixed labeled right lower lobe and consists of a pink and dark red piece of lung with a long stapled margin. The specimen measures 12 by 2.5 by 2 cm. There is a defect in the pleural surface measuring 1.1 x 1 cm. There is an adjacent firm white mass measuring 1.7 cm in greatest dimension. The pleural surface is distorted over the tumor. A portion of specimen is taken for research purposes. On cut section the tumor is 1.8 cm in greatest dimension. Sections after fixation.

Specimen B. is received unfixed labeled reexcision of staple line and consists of a dark red and pink piece of lung tissue with a stapled margin. The specimen measures 8 by 1.8 by 1 cm. Sections after fixation.

HIIPA Discrepancy		

Source: NCI Genomic Data Commons file 96d6d72c-6065-45ae-8eda-ae3d663f96f4 (TCGA-44-A4SU.14019D02-C4EC-4EA7-8AEB-255A14EB8D07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).